Gene-level copy-number profile of tumor specimen C3L-05973-02 from CPTAC case C3L-05973, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.5 years (25,391 days).
Specimen C3L-05973-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f36d3439-b23d-4952-ab96-bd42c46c4be9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05973-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/3cf82d8e-3da7-4d5c-b450-5ed4c764c7fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 315; copy number 1: 13,133; copy number 2: 40,033; copy number 3: 5,157; copy number 4: 56; copy number 5: 25; copy number 6: 88; copy number 7: 56; copy number 8: 24; copy number 9: 19.

Homozygous deletions (total copy number 0; autosomes only): 315 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:168,920,394–170,738,536, 43 genes: AL513210.1, AL109924.3, AL109924.1, AL109924.2, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr14:105,620,506–105,626,066, 2 genes: IGHG4, MIR8071-1.
- chr16:11,555–1,884,294, 161 genes (within-gene range 0–1) (broad region; genes not listed).
- chr19:917,287–1,748,745, 57 genes: KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C, EFNA2, RPS15P9, AC005330.1, PWWP3A, AC004623.1, AC005329.2, NDUFS7, AC005329.3, AC005329.1, GAMT, DAZAP1, RPS15, AC027307.3, APC2, AC027307.2, C19orf25, PCSK4, REEP6, ADAMTSL5, PLK5, AC027307.1, MEX3D, RN7SL477P, MBD3, AC005943.2, AC005943.1, UQCR11, TCF3, RNU6-1223P, Metazoa_SRP, AC005256.1.
- chr19:2,977,538–4,039,386, 52 genes: TLE6, TLE2, AC005944.1, TLE5, GNA11, AC005262.2, KF456478.1, AC005262.1, GNA15, AC005264.1, S1PR4, NCLN, CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54, RAX2, AC005777.1, MATK, ZFR2, FTLP5, ATCAY, RN7SL202P, NMRK2, DAPK3, MIR637, EEF2, SNORD37, PIAS4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 212 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:485,154–693,139, 2 genes, copy number 7 (within-gene range 3–7): EXOC2, AL031770.1.
- chr6:958,323–1,314,758, 4 genes, copy number 7 (within-gene range 3–7): LINC01622, AL033381.2, AL033381.1, FOXQ1.
- chr6:2,765,393–2,786,952, 1 gene, copy number 8: WRNIP1.
- chr6:4,979,072–5,089,487, 6 genes, copy number 5: AL359643.1, RPP40, LYRM4-AS1, AL359643.2, AL139094.1, PPP1R3G.
- chr6:8,073,360–8,102,559, 1 gene, copy number 7 (within-gene range 3–7): EEF1E1.
- chr6:8,435,568–9,294,133, 3 genes, copy number 7: HULC, AL161437.1, AL137220.1.
- chr6:14,597,514–14,646,638, 2 genes, copy number 6: AL109914.1, RNU6-793P.
- chr6:17,615,035–17,706,925, 1 gene, copy number 7 (within-gene range 3–7): NUP153.
- chr6:17,706,257–17,737,556, 3 genes, copy number 7: AL138724.1, RNA5SP204, Y_RNA.
- chr6:20,042,455–20,317,739, 4 genes, copy number 7: AL008627.1, MBOAT1, AL158198.1, AL158198.2.
- chr6:20,421,583–20,421,887, 1 gene, copy number 7 (within-gene range 3–7): RN7SL128P.
- chr6:21,354,411–21,523,783, 3 genes, copy number 7: AL031767.1, LINC00581, AL512380.1.
- chr6:22,287,244–22,593,833, 3 genes, copy number 7: PRL, HDGFL1, AL033539.1.
- chr6:26,440,472–26,519,458, 4 genes, copy number 7: BTN3A3, BTN2A1, BTN1A1, RNU6-502P.
- chr6:30,132,805–30,213,427, 6 genes, copy number 8: AL669914.1, TRIM40, TRIM10, TRIM15, TRIM26, PAIP1P1.
- chr6:32,549,940–32,668,383, 6 genes, copy number 6: RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.
- chr6:33,620,365–33,804,003, 7 genes, copy number 5: ITPR3, UQCC2, MIR3934, IP6K3, LEMD2, MLN, AL138889.3.
- chr6:33,999,972–34,000,051, 1 gene, copy number 5: MIR1275.
- chr6:34,189,780–34,426,071, 10 genes, copy number 6: KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10.
- chr6:34,792,015–35,091,406, 8 genes, copy number 6: UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1.
- chr6:37,170,152–37,332,970, 6 genes, copy number 7: PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2.
- chr6:37,507,348–37,699,306, 6 genes, copy number 6: LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1.
- chr6:41,770,176–42,050,357, 12 genes, copy number 7 (within-gene range 3–7): FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3.
- chr6:42,564,029–42,868,560, 6 genes, copy number 6: UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL.
- chr6:50,818,723–50,913,256, 4 genes, copy number 6: TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr6:52,657,373–52,909,698, 14 genes, copy number 8: AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3.
- chr6:56,431,950–56,433,213, 1 gene, copy number 8: RCC2P7.
- chr6:60,719,222–60,723,898, 2 genes, copy number 8: GAPDHP41, AL590227.1.
- chr6:63,193,072–63,193,630, 1 gene, copy number 7: AL450346.1.
- chr6:63,392,222–72,403,143, 79 genes, copy number 5–9 (within-gene range 1–10) (broad region; genes not listed).
- chr21:8,759,077–8,880,976, 5 genes, copy number 6: LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1.

Autosomal genes at a single copy (total copy number 1): 10,277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
